Somatic mutation profile of tumor specimen C3L-02963-03 (aliquot CPT0197090009) from CPTAC case C3L-02963, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 71.2 years (25,991 days).
Specimen C3L-02963-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ea25de7-f3df-442a-8f15-02adccb9f892.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02963-31 (Blood Derived Normal), aliquot CPT0197830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa93407e-dab7-44db-a28a-3170de6eb0a6

The open-access MAF lists 178 somatic variants for this specimen: 117 protein-altering or splice-affecting, 37 silent, 24 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 103, Silent 37, Nonsense Mutation 9, Intron 8, 5'UTR 6, RNA 5, 3'UTR 3, Splice Region 3, Frame Shift Del 1, 3'Flank 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.4159G>T p.E1387* | Nonsense Mutation (SNP) | VAF 63/421 reads (15%) | catalogued as rs878853369; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 44/407 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC144573.1 | c.754C>T p.L252F | Missense Mutation (SNP) | VAF 132/364 reads (36%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.161); catalogued as rs1406705994; called by muse, mutect2, varscan2
- ANK3 | c.2548G>C p.E850Q | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV99783173; called by muse, mutect2
- ANKIB1 | c.877C>G p.P293A | Missense Mutation (SNP) | VAF 29/511 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.214); catalogued as COSV56066700; called by muse, mutect2
- ATP10A | c.1787G>T p.R596M | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV100791507, COSV100791573; called by muse, mutect2
- ATP1A2 | c.1492C>G p.Q498E | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs970074764; called by muse, mutect2
- CAPRIN1 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 36/402 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.643); catalogued as rs550457097, COSV58220928; called by muse, mutect2
- CDH17 | c.929C>T p.A310V | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0.221); catalogued as COSV50340796; called by muse, mutect2
- CLVS2 | c.835G>T p.D279Y | Missense Mutation (SNP) | VAF 24/328 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99252337; called by muse, mutect2
- COPG1 | c.910C>T p.R304C | Missense Mutation (SNP) | VAF 7/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1192296094, COSV59114932; called by muse, mutect2
- CST11 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 13/182 reads (7%) | SIFT tolerated (0.94); PolyPhen benign (0.157); catalogued as COSV100983590; called by muse, mutect2
- CUBN | c.9414G>C p.Q3138H | Missense Mutation (SNP) | VAF 42/458 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV64729116; called by muse, mutect2
- DMXL2 | c.8971C>T p.R2991* | Nonsense Mutation (SNP) | VAF 25/417 reads (6%) | catalogued as rs775750727, COSV51840432; called by muse, mutect2
- EFCAB3 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as COSV71584829; called by muse, mutect2
- F5 | c.2707G>T p.G903* | Nonsense Mutation (SNP) | VAF 28/167 reads (17%) | catalogued as COSV63122080; called by muse, mutect2, varscan2
- FAM135B | c.4015G>C p.G1339R | Missense Mutation (SNP) | VAF 25/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99423874; called by muse, mutect2, varscan2
- HAPLN1 | c.223C>A p.H75N | Missense Mutation (SNP) | VAF 12/175 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as COSV57151182; called by muse, mutect2
- HES1 | c.205-6A>G | Splice Region (SNP) | VAF 30/326 reads (9%) | catalogued as rs370952700; called by muse, mutect2
- HPRT1 | c.113C>G p.P38R | Missense Mutation (SNP) | VAF 20/144 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM002613, COSV53778669; called by muse, mutect2, varscan2
- HTR3A | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 20/346 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs540212344, COSV55468983; called by muse, mutect2
- IRF2BP1 | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 19/465 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as COSV56192888; called by muse, mutect2
- ISL2 | c.701T>C p.V234A | Missense Mutation (SNP) | VAF 32/374 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51957125; called by muse, mutect2
- KLK3 | c.391G>T p.E131* | Nonsense Mutation (SNP) | VAF 26/349 reads (7%) | catalogued as rs182759459, COSV58098938; called by muse, mutect2
- MAGEB3 | c.1004G>A p.C335Y | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs776655301; called by muse, mutect2, varscan2
- MYT1L | c.424G>C p.D142H | Missense Mutation (SNP) | VAF 17/167 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.4); catalogued as COSV67720977; called by muse, mutect2, varscan2
- NLRP7 | c.544G>A p.V182M | Missense Mutation (SNP) | VAF 17/257 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.668); catalogued as rs778545569, CM1210279, COSV60172027; called by muse, mutect2
- PAGE5 | c.209C>A p.P70H | Missense Mutation (SNP) | VAF 23/147 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99215764; called by muse, mutect2, varscan2
- PCDHB12 | c.1392C>G p.N464K | Missense Mutation (SNP) | VAF 64/686 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.938); catalogued as COSV99507981; called by muse, mutect2
- PIGA | c.863G>A p.G288E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61236880; called by muse, mutect2, varscan2
- PLEKHA4 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 18/297 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.342); catalogued as COSV99612558; called by muse, mutect2
- PLXNB2 | c.3743G>A p.R1248H | Missense Mutation (SNP) | VAF 40/271 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1332220132; called by muse, mutect2, varscan2
- PLXNB2 | c.1798C>T p.R600* | Nonsense Mutation (SNP) | VAF 26/238 reads (11%) | catalogued as rs1333488993, COSV63780558; called by muse, mutect2, varscan2
- PTK6 | c.973C>G p.L325V | Missense Mutation (SNP) | VAF 26/352 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV53917099; called by muse, mutect2
- RADIL | c.3052G>A p.G1018R | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); catalogued as rs199603613; called by muse, mutect2
- RFPL2 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 32/448 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.505); catalogued as COSV50710928; called by muse, mutect2
- RFX8 | c.378G>T p.K126N (on ENST00000646446; = p.K55N on NM_001145664.2 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/149 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV65178290; called by muse, mutect2
- SDK1 | c.3635G>A p.R1212K | Missense Mutation (SNP) | VAF 51/440 reads (12%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.996); catalogued as COSV67383819; called by muse, mutect2, varscan2
- SYNE1 | c.2397C>T p.V799= (on ENST00000367255 / NM_182961.4; = p.V806= on NM_033071.3) | Splice Region (SNP) | VAF 28/284 reads (10%) | catalogued as rs1006310552; called by muse, mutect2
- TBP | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 18/237 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs756227958, COSV57830402; called by muse, mutect2
- TBX21 | c.1162G>C p.G388R | Missense Mutation (SNP) | VAF 53/392 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.159); catalogued as COSV99456241; called by mutect2, varscan2
- TLR3 | c.946C>T p.H316Y | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as rs1199986151, COSV57168047; called by muse, mutect2
- TRIM15 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 27/388 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as COSV64990403; called by muse, mutect2
- TTN | c.912C>A p.V304= | Splice Region (SNP) | VAF 9/230 reads (4%) | catalogued as COSV100623063; called by muse, mutect2
- ZIM2 | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 20/229 reads (9%) | catalogued as COSV55642689; called by muse, mutect2
- ZNF208 | c.3691G>T p.G1231C | Missense Mutation (SNP) | VAF 12/343 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs1374817536; called by muse, mutect2
- ZNF831 | c.3229C>T p.R1077C | Missense Mutation (SNP) | VAF 20/237 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs200262179, COSV64042575, COSV64045451; called by muse, mutect2
- ADAMTS19 | c.3275C>G p.S1092* | Nonsense Mutation (SNP) | VAF 17/168 reads (10%) | called by muse, mutect2, varscan2
- ADGRF2 | c.1800G>A p.M600I (on ENST00000296862 / NM_001368115.2; = p.M532I on NM_153839.7) | Missense Mutation (SNP) | VAF 16/213 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.028); called by muse, mutect2
- ALPK2 | c.872C>T p.A291V | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AVIL | c.2091G>T p.Q697H | Missense Mutation (SNP) | VAF 15/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCL6B | c.839A>T p.Q280L | Missense Mutation (SNP) | VAF 28/285 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- BNC2 | c.202T>G p.L68V | Missense Mutation (SNP) | VAF 27/562 reads (5%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.074); called by muse, mutect2
- BRINP1 | c.1632G>C p.M544I | Missense Mutation (SNP) | VAF 19/169 reads (11%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- C7orf33 | c.190A>C p.T64P | Missense Mutation (SNP) | VAF 21/200 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- CACNA1E | c.4006C>A p.H1336N | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2
- CD226 | c.272T>A p.M91K | Missense Mutation (SNP) | VAF 17/357 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.015); called by muse, mutect2
- CNOT1 | c.2800G>A p.A934T | Missense Mutation (SNP) | VAF 14/364 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2
- CTXN2 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 12/380 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); called by muse, mutect2
- CUBN | c.9413A>T p.Q3138L | Missense Mutation (SNP) | VAF 42/462 reads (9%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- CUL9 | c.2738C>G p.T913R | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- DRD2 | c.829C>G p.Q277E | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2
- E2F5 | c.578C>T p.P193L | Missense Mutation (SNP) | VAF 12/245 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- EGFL6 | c.1550G>T p.S517I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2, varscan2
- FAM71E2 | c.19A>T p.R7W | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- FNIP2 | c.3287C>T p.P1096L | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GABRB3 | c.361A>T p.T121S | Missense Mutation (SNP) | VAF 19/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GJA8 | c.1277C>G p.A426G | Missense Mutation (SNP) | VAF 72/556 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- GPRC6A | c.2060C>A p.A687D | Missense Mutation (SNP) | VAF 27/297 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GRIN2A | c.4189A>G p.N1397D | Missense Mutation (SNP) | VAF 31/454 reads (7%) | SIFT tolerated (0.54); PolyPhen benign (0.253); called by muse, mutect2
- IFIT3 | c.5+1G>A p.X2_splice | Splice Site (SNP) | VAF 20/240 reads (8%) | called by muse, mutect2
- KIF13A | c.1178A>G p.K393R | Missense Mutation (SNP) | VAF 9/219 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.04); called by muse, mutect2
- KSR2 | c.242A>G p.E81G | Missense Mutation (SNP) | VAF 12/209 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); called by muse, mutect2
- LRRC32 | c.1829T>C p.L610P | Missense Mutation (SNP) | VAF 12/280 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2
- MED23 | c.195G>C p.K65N | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.005); called by muse, mutect2
- MMAB | c.465G>C p.Q155H | Missense Mutation (SNP) | VAF 42/694 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- MMP17 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.378); called by muse, mutect2
- MUC17 | c.2329C>A p.H777N | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- MYOCD | c.1379C>A p.P460Q | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NLRP13 | c.1512G>C p.E504D | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.321); called by muse, mutect2
- NLRP4 | c.1474A>G p.R492G | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.173); called by muse, mutect2
- NSDHL | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 30/253 reads (12%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OPCML | c.719G>T p.G240V | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.775); called by muse, mutect2
- OR2J1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- P2RY8 | c.969G>T p.E323D | Missense Mutation (SNP) | VAF 14/453 reads (3%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2
- PEX5L | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PIGA | c.1335G>A p.M445I | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLS3 | c.1226C>G p.S409C | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1R9A | c.970C>A p.P324T | Missense Mutation (SNP) | VAF 18/314 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2
- PPP4R3C | c.2478G>C p.K826N | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by mutect2, varscan2
- PRDX6 | c.605del p.F202Sfs*121 | Frame Shift Del (DEL) | VAF 27/240 reads (11%) | called by mutect2, pindel, varscan2
- PTPRH | c.2513T>A p.V838E | Missense Mutation (SNP) | VAF 36/368 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- PTPRQ | c.1304C>T p.P435L (on ENST00000616559; = p.P393L on NM_001145026.2) | Missense Mutation (SNP) | VAF 19/352 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.775); called by muse, mutect2
- PTPRT | c.2640G>T p.Q880H | Missense Mutation (SNP) | VAF 34/499 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- RECK | c.1516G>A p.E506K | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.065); called by muse, mutect2
- RIPK2 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHANK3 | c.4681C>T p.R1561C | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.197); called by muse, mutect2
- SLCO2A1 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 45/440 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLCO6A1 | c.464C>G p.S155C | Missense Mutation (SNP) | VAF 25/288 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- STK39 | c.1573T>C p.C525R | Missense Mutation (SNP) | VAF 18/260 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- STYXL2 | c.3292G>C p.E1098Q | Missense Mutation (SNP) | VAF 29/477 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.374); called by muse, mutect2
- TEKT5 | c.961G>T p.E321* | Nonsense Mutation (SNP) | VAF 28/572 reads (5%) | called by muse, mutect2
- TEX15 | c.1126A>T p.S376C (on ENST00000256246; = p.S759C on NM_001350162.2) | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); called by muse, mutect2
- THEGL | c.1349C>T p.A450V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, varscan2
- TNRC18 | c.1614G>C p.E538D | Missense Mutation (SNP) | VAF 44/410 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- TP53TG5 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 21/368 reads (6%) | SIFT tolerated (0.46); PolyPhen benign (0.241); called by muse, mutect2
- TRPS1 | c.81A>C p.E27D (on ENST00000220888 / NM_001330599.2; = p.E40D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/224 reads (5%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.101); called by muse, mutect2
- TSPAN9 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 27/430 reads (6%) | SIFT tolerated (0.48); PolyPhen benign (0.068); called by muse, mutect2
- TTN | c.98746C>G p.Q32916E (on ENST00000591111; = p.Q25492E on NM_003319.4) | Missense Mutation (SNP) | VAF 24/457 reads (5%) | PolyPhen benign (0.194); called by muse, mutect2
- UGGT1 | c.47T>G p.L16R | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); called by muse, mutect2
- USH2A | c.12826A>T p.M4276L | Missense Mutation (SNP) | VAF 31/216 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- VANGL1 | c.414G>T p.W138C | Missense Mutation (SNP) | VAF 17/204 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- WDFY4 | c.649G>C p.E217Q | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- ZFHX4 | c.10588C>T p.L3530F | Missense Mutation (SNP) | VAF 20/286 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2
- ZNF383 | c.1003G>T p.E335* | Nonsense Mutation (SNP) | VAF 23/199 reads (12%) | called by muse, mutect2, varscan2
- ZNF536 | c.735C>A p.N245K | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.94); PolyPhen benign (0.051); called by muse, mutect2
- ZNF536 | c.2501G>A p.R834K | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- CAMSAP1 | c.2298G>C p.G766= | Silent (SNP) | VAF 26/360 reads (7%) | catalogued as COSV100409884; called by muse, mutect2
- CDH9 | c.1818C>A p.I606= | Silent (SNP) | VAF 38/382 reads (10%) | catalogued as rs762551054, COSV50318599; called by muse, mutect2
- CDKN2B | c.180C>A p.R60= | Silent (SNP) | VAF 45/576 reads (8%) | catalogued as rs764199965; called by muse, mutect2
- CERKL | c.204G>C p.L68= | Silent (SNP) | VAF 10/102 reads (10%) | called by muse, mutect2, varscan2
- CLEC6A | c.87A>G p.A29= | Silent (SNP) | VAF 28/392 reads (7%) | called by muse, mutect2
- CTAG2 | c.234C>T p.C78= | Silent (SNP) | VAF 12/208 reads (6%) | catalogued as COSV99908734; called by muse, mutect2
- DACT1 | c.1449G>T p.G483= | Silent (SNP) | VAF 33/303 reads (11%) | called by muse, mutect2, varscan2
- DNAH7 | c.8689C>T p.L2897= | Silent (SNP) | VAF 29/306 reads (9%) | called by muse, mutect2
- DPH6 | c.561C>G p.L187= | Silent (SNP) | VAF 13/190 reads (7%) | called by muse, mutect2
- ELAVL3 | c.600C>A p.V200= | Silent (SNP) | VAF 26/670 reads (4%) | called by muse, mutect2
- FFAR2 | c.765G>T p.R255= | Silent (SNP) | VAF 46/484 reads (10%) | called by muse, mutect2
- GABRA2 | c.1050A>C p.V350= | Silent (SNP) | VAF 16/222 reads (7%) | called by muse, mutect2
- HCN4 | c.39C>T p.Y13= | Silent (SNP) | VAF 28/482 reads (6%) | called by muse, mutect2
- IGFBP1 | c.474T>C p.Y158= | Silent (SNP) | VAF 16/228 reads (7%) | called by muse, mutect2
- LAIR2 | c.114G>T p.V38= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as rs762339729; called by muse, mutect2
- LRRK2 | c.2752C>A p.R918= | Silent (SNP) | VAF 19/243 reads (8%) | catalogued as COSV100109364, COSV100111395; called by muse, mutect2
- MDN1 | c.7521T>G p.T2507= | Silent (SNP) | VAF 12/338 reads (4%) | called by muse, mutect2
- MEIOC | c.2703C>T p.A901= | Silent (SNP) | VAF 29/267 reads (11%) | called by muse, mutect2
- PIGA | c.1107G>A p.G369= | Silent (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
- PIK3C2G | c.654A>G p.E218= | Silent (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- PREX1 | c.1146G>A p.K382= | Silent (SNP) | VAF 30/344 reads (9%) | called by muse, mutect2
- PRKAR2B | c.525C>G p.V175= | Silent (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- PROM2 | c.510C>G p.V170= | Silent (SNP) | VAF 22/279 reads (8%) | called by muse, mutect2
- REV1 | c.3483A>T p.G1161= | Silent (SNP) | VAF 9/176 reads (5%) | called by muse, mutect2
- SLC10A4 | c.192G>A p.P64= | Silent (SNP) | VAF 50/221 reads (23%) | catalogued as rs1340289358; called by muse, mutect2, varscan2
- SMPDL3A | c.447G>C p.L149= | Silent (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2, varscan2
- SYNJ1 | c.2646A>G p.P882= | Silent (SNP) | VAF 18/206 reads (9%) | catalogued as rs1198781961, COSV59150983; called by muse, mutect2
- TBX19 | c.946C>T p.L316= | Silent (SNP) | VAF 16/408 reads (4%) | called by muse, mutect2
- TMEM30A | c.996T>C p.V332= | Silent (SNP) | VAF 11/231 reads (5%) | called by muse, mutect2
- TOGARAM2 | c.951G>A p.Q317= | Silent (SNP) | VAF 23/472 reads (5%) | called by muse, mutect2
- TSHZ2 | c.825G>T p.L275= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as COSV100296486; called by muse, mutect2
- TTN | c.38121C>T p.H12707= (on ENST00000591111; = p.H5283= on NM_003319.4) | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as rs1060503970; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE2Q1 | c.42G>T p.P14= | Silent (SNP) | VAF 4/24 reads (17%) | called by muse, mutect2
- UBE3D | c.522C>T p.T174= | Silent (SNP) | VAF 18/416 reads (4%) | called by muse, mutect2
- USH2A | c.1308C>T p.V436= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- ZAR1 | c.699G>T p.A233= | Silent (SNP) | VAF 33/157 reads (21%) | catalogued as rs1262970999; called by muse, mutect2, varscan2
- ZDHHC14 | c.708A>G p.S236= | Silent (SNP) | VAF 11/187 reads (6%) | catalogued as COSV100399296; called by muse, mutect2
- AC068473.1 | n.573C>G | RNA (SNP) | VAF 25/392 reads (6%) | called by muse, mutect2
- AC133561.1 | n.1603C>A | RNA (SNP) | VAF 10/312 reads (3%) | called by muse, mutect2
- AK2 | c.*1705C>T | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- CSGALNACT1 | c.*1009C>G | 3'UTR (SNP) | VAF 37/384 reads (10%) | called by muse, mutect2
- DCHS2 | n.7141C>A | RNA (SNP) | VAF 15/150 reads (10%) | called by muse, mutect2, varscan2
- DDX3Y | c.-52A>G | 5'UTR (SNP) | VAF 13/77 reads (17%) | called by muse, mutect2, varscan2
- FAM166C | c.462-483C>G | Intron (SNP) | VAF 28/422 reads (7%) | called by muse, mutect2
- GCKR | c.644+486C>A | Intron (SNP) | VAF 6/142 reads (4%) | called by muse, mutect2
- GGCX | c.-15C>T | 5'UTR (SNP) | VAF 18/183 reads (10%) | catalogued as rs759825656; called by muse, mutect2, varscan2
- IKBKB | c.1125+106A>C | Intron (SNP) | VAF 11/110 reads (10%) | called by muse, mutect2, varscan2
- ITSN1 | c.2728-839C>T | Intron (SNP) | VAF 32/524 reads (6%) | called by muse, mutect2
- LAPTM4B | c.-68C>A | 5'UTR (SNP) | VAF 27/423 reads (6%) | catalogued as rs751715895; called by muse, mutect2
- LINC00602 | n.1281G>T | RNA (SNP) | VAF 17/189 reads (9%) | called by muse, mutect2
- MIR517A | n.6G>T | RNA (SNP) | VAF 7/79 reads (9%) | catalogued as rs1237915920; called by muse, mutect2
- MLIP | c.612+12011C>A | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- MON1B | c.476-41G>T | Intron (SNP) | VAF 7/170 reads (4%) | called by muse, mutect2
- NLGN4Y | c.*1147A>T | 3'UTR (SNP) | VAF 19/158 reads (12%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141157722 G>A | 3'Flank (SNP) | VAF 60/924 reads (6%) | called by muse, mutect2
- RNU7-174P | chr8:80559587 G>T | 5'Flank (SNP) | VAF 100/573 reads (17%) | called by muse, mutect2, varscan2
- SLC38A11 | c.-27C>T | 5'UTR (SNP) | VAF 23/381 reads (6%) | called by muse, mutect2
- SRRM2 | c.7734-121C>T | Intron (SNP) | VAF 21/242 reads (9%) | catalogued as rs540867177; called by muse, mutect2
- TFDP2 | c.-29A>G | 5'UTR (SNP) | VAF 6/20 reads (30%) | called by muse, mutect2, varscan2
- TIMM8A | c.132+196C>T | Intron (SNP) | VAF 8/77 reads (10%) | called by muse, mutect2
- ZNF2 | c.-14G>T | 5'UTR (SNP) | VAF 32/432 reads (7%) | called by muse, mutect2
